Surgical pathology report (de-identified scan), TCGA case TCGA-MM-A84U, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MM-A84U-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

PATHOLOGIC DIAGNOSIS

KIDNEY, LEFT, LEFT PARTIAL NEPHRECTOMY:

- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL TYPE)
- TUMOR SIZE: GREATEST DIMENSION: 3.7 CM
- ADDITIONAL DIMENSIONS: 2.7 x 2.0 CM
- TUMOR FOCALITY: UNIFOCAI
- MACROSCOPIC EXTENT OF TUMOR: TUMOR LIMITED TO KIDNEY
- HISTOLOGIC TYPE CLEAR CELL RENAL CELL CARCINOMA
- SARCOMATOID FEATURES: NOT IDENTIFIED
- TUMOR NECROSIS: PRESENT, PATCHY
- HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): G4 (NUCLEI BIZARRE AND MULTILOBATED, 20 MICROMETER OR GREATER, NUCLEOLI PROMINENT, CHROMATIN CLUMPED)
- MICROSCOPIC TUMOR EXTENSION: TUMOR LIMITED TO KIDNEY
- MARGINS:
- RENAL CAPSULAR MARGIN INVOLVED BY CARCINOMA
- lymph-VASCULAR INVASION: NOT IDENTIFIED
- PATHOLOGIC STAGING: STAGE I
- PRIMARY TUMOR (pT): pT1a (tumor less than 4 cm, confined to kidney)
- regional lymph nodes (pN): pNX (lymph nodes can't be assessed)
- distant metastasis (pM): not applicable
- ADDITIONAL FINDINGS: INTERSTITIAL CHRONIC INFLAMMATION SCLEROTIC GLOMERULI

Staff Pathologist

Pertinent Clinical Information

None given.

Gross Description

Specimen Material: Left renal mass.

The specimen is received fresh for intraoperative consultation and consists of a 25 gram, 3.7 x 2.7 x 2.0 cm mass. The external surface is tan-red-brown, smooth and glistening. The possible surgical resection margin is inked blue and the external surface of the specimen is inked black and the specimen is serially sectioned to reveal a well circumscribed,

ICD-O-3

Carcinoma, clear cell 8310/3

Site @ Kidney NOS 064.9

9/27/14

[page 2 of 2]
encapsulated, partially cystic mass with areas of hemorrhage and necrosis. The mass involves the inked cortical surface of the kidney without involving the perinephric fatty tissue. A 2.0 x 0.9 x 0.4 cm apparently normal parenchyma is identified at the resection margin. The specimen is submitted in its entirety in cassettes 1-8.

Pathology Resident
Microscopic Description
Performed.

This case was reviewed by the staff pathologist listed below.

Pathology Resident
Electronically Signed Out

Qual/Synchronous: Primary Note		

Source: NCI Genomic Data Commons file 0e868e0b-4386-4381-8e08-84a802131dfe (TCGA-MM-A84U.AF175E00-A8D2-4F97-BC7E-258575BA15FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).